Gene-level copy-number profile of tumor specimen TCGA-VS-A9UR-01A from TCGA case TCGA-VS-A9UR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 53.9 years (19,688 days).
Specimen TCGA-VS-A9UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.84cd0e64-327b-4560-8e9f-692037af4426.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8987769-5ff3-4a8f-aa78-edeecd6904d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 10,227; copy number 2: 48,748; copy number 3: 825.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UR-01A-11D-A42N-01): tumor purity 0.8, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:54,239,693–54,954,665, 15 genes: AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1, LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
